Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A6GZ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A6GZ-05A (Additional - New Primary).

[page 1 of 2]
ICD-O-3
Pheochromocytoma 8700/0
Site Adrenal gland NOS
C74.9
QW 8/8/13

Surgical Pathology	Final Results
--------------------	---------------

Surgical Pathology

Final

CASE NUMBER:

DIAGNOSIS:

1. Soft tissue, periaortic (excision): Fibroadipose tissue with cauterized cellular fragment, see Note.
2. Adrenal, left, mass (excision): Pheochromocytoma, no vascular or capsular invasion is seen.

NOTE: In the periaortic soft tissue specimen, there are several fragments of cellular tissue showing cautery artifact. These cells are rounded and have abundant granular eosinophilic cytoplasm. Immunohistochemistry for synaptophysin, chromogranin, and inhibin are performed and are negative. Synaptophysin shows positivity in internal control. We do not feel these cells represent pheochromocytoma. Additional immunohistochemistry to try to characterize these cells will be performed and reported separately.

The immunoperoxidase tests performed here were developed and their performance characteristics determined by the

They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Allocate Order to Protocol: Brief

Clinical History: left

adrenal mass, history of right adrenal
pheochromocytoma Specimen

Taken For Protocol: 01 - Yes

PROCEDURE: Pre-Operative Diagnosis: left adrenal mass Post-Operative
Diagnosis:

left adrenal mass Operative Findings: left adrenal mass
removed

SPECIMENS SUBMITTED: 1. RETROPERITONEAL LESION, Tissue
2. ADRENAL MASS, LEFT

GROSS DESCRIPTION: Received are 2 containers labeled with the patient's name, medical record number, and further specified as follows:

1. Received in a formalin-filled container labeled "periaorta tissue" is a gray to yellow-tan irregular fragment of tissue measuring 1.5 x 1 x 0.6 cm and is submitted in toto in a white cassette labeled #1 for permanent processing.

2. Received fresh in a container labeled "left adrenal mass" is a red/tan soft tissue mass with multiple white staples on one surface measuring 2.7 x 2.2 x 2 cm and weighing 13.3 grams. The specimen is sectioned revealing a solid tan/red cut surface with multiple small foci

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By:

Do not file in Medical Record

[page 2 of 2]
Surgical Pathology

Final Results

of hemorrhage. Approximately 40% is procured for the
40% procured for and the remaining tissue sent
to Surgical Pathology. Inking is not required as per
Procurement is carried out by on at hour.
The specimen received at the Laboratory of Pathology is consistent with
the above description. is sectioned and submitted in toto in white
cassettes labeled or permanent processing.

Gross description dictated by

No consultants

#

#

7/25/13 (initials)

Pr. or Malignancy History		✓

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974

Requested By:

Do not file in Medical Record

Source: NCI Genomic Data Commons file 43d06f61-477b-451f-8929-f4133e7431c0 (TCGA-QR-A6GZ.9BCAD0F3-ECA4-4522-843A-AECDEF712DC2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).